Somatic mutation profile of tumor specimen TARGET-30-PATXHT-01A (aliquot TARGET-30-PATXHT-01A-01D) from TARGET case TARGET-30-PATXHT, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.2 years (1,182 days).
Specimen TARGET-30-PATXHT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70827bdc-dadb-488b-b26f-2298a3b38548.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATXHT-10A (Blood Derived Normal), aliquot TARGET-30-PATXHT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ceed6f5f-86fe-4e13-b5d8-cb432b902f60

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL12A1 | c.4854C>A p.S1618R | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV59412134; called by muse, mutect2, varscan2
- KCNS2 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.058); catalogued as COSV54641710; called by muse, mutect2, varscan2
- NUDT22 | c.635A>C p.N212T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV54176337; called by muse, mutect2, varscan2
- PPP4R4 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV58559600; called by muse, mutect2, varscan2
- TET2 | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 71/137 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs762289112, COSV54438611; called by muse, mutect2, varscan2
- ATN1 | c.2448G>A p.E816= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV63113503; called by muse, mutect2, varscan2
- PIGQ | c.1532-618G>T | Intron (SNP) | VAF 19/38 reads (50%) | catalogued as COSV50324593; called by muse, mutect2, varscan2
